Somatic mutation profile of tumor specimen ALCH-AFFT-TTP1-A (aliquot ALCH-AFFT-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AFFT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 77.0 years (28,124 days).
Specimen ALCH-AFFT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61afa379-b629-4755-91c5-0d0068e06721.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFFT-NB1-A (Blood Derived Normal), aliquot ALCH-AFFT-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81f27dce-2a5e-483a-bacd-e059acf2703c

The open-access MAF lists 302 somatic variants for this specimen: 203 protein-altering or splice-affecting, 64 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 170, Silent 64, Nonsense Mutation 17, Intron 16, RNA 7, 3'UTR 7, Splice Site 6, Frame Shift Del 4, Frame Shift Ins 3, 5'UTR 3, 5'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 22/94 reads (23%) | catalogued as rs121913382, COSV58682685, COSV58683250; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | hotspot (GDC flag); catalogued as rs1567555934, COSV52694629; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACADL | c.188G>A p.S63N | Missense Mutation (SNP) | VAF 77/372 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.109); catalogued as COSV52052757; called by muse, mutect2, varscan2
- ACTN2 | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 49/378 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as rs764315978, COSV63978997; called by muse, mutect2, varscan2
- ADGRG7 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as rs749092040, COSV99841121; called by muse, mutect2, varscan2
- AMBN | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as rs777785704, COSV59826924; called by muse, mutect2, varscan2
- ARHGAP30 | c.1996G>A p.G666R | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs1237782190; called by muse, mutect2, varscan2
- ATAD2 | c.1958G>T p.R653L | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54879547; called by muse, mutect2, varscan2
- ATP9B | c.1412-1G>A p.X471_splice | Splice Site (SNP) | VAF 35/71 reads (49%) | catalogued as rs1199852243; called by muse, mutect2, varscan2
- BRINP2 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as rs1558180239, COSV64177987; called by muse, varscan2
- CADPS | c.3004C>T p.R1002W | Missense Mutation (SNP) | VAF 19/254 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs1232952891; called by muse, mutect2
- CADPS2 | c.2923C>T p.P975S | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV57388462; called by muse, mutect2, varscan2
- CATSPER1 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 75/402 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs754197714; called by muse, mutect2, varscan2
- CAVIN3 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.133); catalogued as rs538451811; called by muse, mutect2, varscan2
- CBY2 | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as COSV60120122; called by muse, mutect2, varscan2
- CHRNA1 | c.1037G>T p.R346L (on ENST00000261007 / NM_001039523.3; = p.R321L on NM_000079.4) | Missense Mutation (SNP) | VAF 34/327 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV53682061, COSV53683259; called by muse, mutect2
- CNTN5 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54341795; called by muse, mutect2
- CSGALNACT2 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 31/348 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.515); catalogued as COSV65675480; called by muse, mutect2
- CSMD1 | c.5458C>A p.P1820T (on ENST00000520002; = p.P1819T on NM_033225.6) | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59344645; called by muse, mutect2, varscan2
- CSMD1 | c.4220G>T p.S1407I (on ENST00000520002; = p.S1406I on NM_033225.6) | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs759772657; called by muse, mutect2, varscan2
- CSMD3 | c.10004G>C p.G3335A (on ENST00000297405 / NM_001363185.1; = p.G3166A on NM_052900.3) | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.705); catalogued as rs1215511339, COSV52224909; called by muse, varscan2
- CUBN | c.3598G>A p.G1200S | Missense Mutation (SNP) | VAF 71/380 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs762516302; called by muse, mutect2, varscan2
- DCAF12L2 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63580691; called by muse, mutect2, varscan2
- DIO2 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 28/120 reads (23%) | catalogued as COSV70445047; called by mutect2, varscan2
- DOCK11 | c.2174A>G p.K725R | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as COSV52247098; called by muse, mutect2, varscan2
- F5 | c.2420G>T p.G807V | Missense Mutation (SNP) | VAF 48/369 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs1443734576; called by muse, mutect2, varscan2
- FAM133A | c.437C>A p.T146K | Missense Mutation (SNP) | VAF 98/326 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.231); catalogued as COSV59074132; called by muse, mutect2, varscan2
- FMN2 | c.4965G>C p.E1655D | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs201067071; called by muse, mutect2, varscan2
- FOXI1 | c.832C>T p.L278F | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.039); catalogued as rs1214856511; called by muse, mutect2, varscan2
- GMNC | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 56/497 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs768871405; called by muse, mutect2, varscan2
- GPC1 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs200876630; called by muse, mutect2, varscan2
- GPR4 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.213); catalogued as rs753457588; called by muse, mutect2, varscan2
- IGKV1D-8 | c.6C>A p.D2E | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.168); catalogued as rs773502877; called by muse, mutect2, varscan2
- KCNH4 | c.2050C>T p.L684F | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434480620; called by muse, mutect2, varscan2
- LILRA4 | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as COSV52494322; called by muse, mutect2, varscan2
- LIPG | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 183/528 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs774602635; called by muse, mutect2, varscan2
- LRRTM1 | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV54440284; called by muse, mutect2, varscan2
- MAGEC1 | c.2342C>A p.S781Y | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); catalogued as rs756572276, COSV53583206; called by muse, mutect2, varscan2
- MPO | c.633C>A p.Y211* | Nonsense Mutation (SNP) | VAF 19/116 reads (16%) | catalogued as COSV56567916; called by muse, mutect2, varscan2
- MSH6 | c.3513T>A p.D1171E | Missense Mutation (SNP) | VAF 48/522 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD040601, CD160998; called by muse, mutect2
- MYO3B | c.3610G>A p.D1204N | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs776522631; called by muse, mutect2
- NBAS | c.3010C>T p.R1004* | Nonsense Mutation (SNP) | VAF 81/412 reads (20%) | catalogued as rs780108348, CM157039, COSV55743357; called by muse, mutect2, varscan2
- NCDN | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs1347739249, COSV61935751, COSV61936638; called by muse, mutect2
- NFE2L2 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960369; called by muse, mutect2, varscan2
- NOC3L | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV64930319; called by muse, varscan2
- OR1L6 | c.605G>A p.R202H (on ENST00000373684; = p.R166H on NM_001004453.2) | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs142557976; called by muse, mutect2, varscan2
- OR2M2 | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 90/471 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100677239; called by muse, mutect2, varscan2
- OR4A16 | c.132G>T p.W44C | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1361171459, COSV59044833; called by muse, mutect2, varscan2
- OR5F1 | c.527A>G p.H176R | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53549186; called by muse, mutect2
- PCDH15 | c.4827C>G p.S1609R | Missense Mutation (SNP) | VAF 122/596 reads (20%) | SIFT deleterious, low confidence (0.05); catalogued as COSV100905378, COSV64691244; called by muse, mutect2, varscan2
- PLXNA1 | c.2569G>A p.G857S | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.327); catalogued as rs376939175, COSV52532610; called by muse, mutect2, varscan2
- PLXNA4 | c.2870C>A p.S957* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100326997, COSV58124858; called by muse, mutect2, varscan2
- PPFIA4 | c.2918G>A p.R973H (on ENST00000447715; = p.R974H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1410964055, COSV55315741; called by muse, mutect2, varscan2
- PPP6R3 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV55721549; called by muse, mutect2, varscan2
- PRR12 | c.871G>T p.A291S (on ENST00000615927; = p.A1112S on NM_020719.3) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV101330805; called by muse, mutect2, varscan2
- PXDNL | c.703del p.R235Efs*57 | Frame Shift Del (DEL) | VAF 38/127 reads (30%) | catalogued as COSV62484754; called by mutect2, pindel, varscan2
- RCC1 | c.-226G>A | Splice Region (SNP) | VAF 7/95 reads (7%) | catalogued as COSV63120876; called by muse, mutect2
- RFC1 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100567406; called by muse, mutect2, varscan2
- RIMS1 | c.3088C>T p.R1030* | Nonsense Mutation (SNP) | VAF 26/552 reads (5%) | catalogued as COSV53446586, COSV53477554; called by muse, mutect2
- RORB | c.505G>A p.V169I (on ENST00000396204 / NM_001365023.1; = p.V158I on NM_006914.4) | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs746472889, COSV65333632, COSV65339156; called by muse, mutect2, varscan2
- RP1L1 | c.7144G>A p.A2382T | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs776156711, COSV66762092; called by muse, mutect2, varscan2
- SNAPC4 | c.2636C>A p.S879Y | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV53733666; called by muse, mutect2, varscan2
- TAF1A | c.204C>A p.H68Q | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1398302993; called by muse, mutect2, varscan2
- TENM1 | c.1877-1G>A p.X626_splice | Splice Site (SNP) | VAF 39/92 reads (42%) | catalogued as COSV100950570; called by muse, mutect2, varscan2
- THEG | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV61074199; called by mutect2, varscan2
- THUMPD2 | c.781G>T p.V261L | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.41); catalogued as COSV53186831; called by muse, mutect2
- TLN2 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as rs1172081815; called by muse, mutect2
- TMEM35A | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1209558276, COSV99515706; called by muse, mutect2, varscan2
- TNNT1 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 116/474 reads (24%) | catalogued as COSV99402898; called by mutect2, varscan2
- TRPV4 | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs377518118; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBGCP5 | c.890G>T p.R297I | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1490795109; called by muse, mutect2, varscan2
- UNC79 | c.7547T>A p.V2516E (on ENST00000393151 / NM_001346218.2; = p.V2339E on NM_020818.5) | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV56378465; called by muse, mutect2, varscan2
- VCAN | c.3326T>C p.V1109A | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs377631685; called by muse, mutect2, varscan2
- ZNF440 | c.1217G>T p.R406I | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.173); catalogued as rs960268330; called by muse, mutect2, varscan2
- ZNF729 | c.1603C>G p.Q535E | Missense Mutation (SNP) | VAF 44/333 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs577135284, COSV62603971; called by muse, mutect2, varscan2
- ZNF765 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as rs1160600945; called by muse, mutect2, varscan2
- ABCA8 | c.1596G>C p.L532F | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- ABLIM3 | c.376A>G p.K126E | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADAMTS18 | c.74T>A p.L25Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.11); called by muse, varscan2
- ADCY1 | c.2498A>G p.N833S | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADGRB3 | c.2699C>A p.A900E | Missense Mutation (SNP) | VAF 38/312 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- ADH6 | c.296G>A p.C99Y | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- AHRR | c.1680G>T p.R560S | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ANK1 | c.2179G>A p.V727I | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- APBB1 | c.294G>T p.E98D | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.111); called by muse, varscan2
- ARHGAP30 | c.1997G>A p.G666E | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- B3GALT5 | c.729C>G p.D243E | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- B4GALNT2 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- BNIP3 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); called by muse, mutect2
- BRINP3 | c.180C>A p.Y60* | Nonsense Mutation (SNP) | VAF 46/217 reads (21%) | called by muse, mutect2, varscan2
- CDH12 | c.1467A>G p.I489M | Missense Mutation (SNP) | VAF 47/277 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CDHR2 | c.3290C>G p.S1097C | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CFAP46 | c.7543C>A p.Q2515K | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CFHR5 | c.1346G>T p.C449F | Missense Mutation (SNP) | VAF 56/362 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHL1 | c.3488G>T p.S1163I (on ENST00000397491 / NM_001253387.1; = p.S1179I on NM_006614.4) | Missense Mutation (SNP) | VAF 62/336 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRM3 | c.988G>T p.D330Y | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- CMYA5 | c.7276G>A p.E2426K | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNTNAP2 | c.1985A>T p.Q662L | Missense Mutation (SNP) | VAF 90/525 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CNTNAP4 | c.519A>T p.E173D | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2
- CNTNAP4 | c.2376del p.W792* | Frame Shift Del (DEL) | VAF 28/237 reads (12%) | called by mutect2, varscan2
- CNTRL | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 39/253 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- COL14A1 | c.4829T>A p.L1610Q | Missense Mutation (SNP) | VAF 97/270 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.443); called by muse, varscan2
- DACH1 | c.423C>A p.S141R | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); called by muse, varscan2
- DCTN2 | c.1119+1G>T p.X373_splice (on ENST00000548249 / NM_001261413.2; = p.X378_splice on NM_006400.4) | Splice Site (SNP) | VAF 39/231 reads (17%) | called by muse, mutect2, varscan2
- DENND2A | c.1123+2T>G p.X375_splice | Splice Site (SNP) | VAF 19/114 reads (17%) | called by muse, mutect2, varscan2
- DHX57 | c.2614_2615insGA p.L872Rfs*30 | Frame Shift Ins (INS) | VAF 27/181 reads (15%) | called by pindel, varscan2
- DIP2C | c.377A>T p.D126V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- DSPP | c.1948A>C p.S650R | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- EFL1 | c.2932C>G p.Q978E | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- EOGT | c.73A>G p.N25D | Missense Mutation (SNP) | VAF 126/503 reads (25%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPDR1 | c.421_422insT p.G141Vfs*18 | Frame Shift Ins (INS) | VAF 43/288 reads (15%) | called by mutect2, pindel, varscan2
- EPN2 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 50/122 reads (41%) | called by muse, mutect2, varscan2
- ESPL1 | c.402G>T p.E134D | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ESPL1 | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- FAM47C | c.1383T>A p.S461R | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- FIGNL1 | c.300G>T p.W100C | Missense Mutation (SNP) | VAF 49/427 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FIGNL1 | c.299G>A p.W100* | Nonsense Mutation (SNP) | VAF 48/422 reads (11%) | called by muse, mutect2, varscan2
- FILIP1 | c.2029C>T p.L677F | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); called by muse, mutect2
- FSIP1 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.058); called by muse, mutect2
- FUOM | c.157C>A p.L53M | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- GRHL3 | c.1693G>C p.G565R (on ENST00000350501 / NM_198174.3; = p.G570R on NM_021180.3) | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GTDC1 | c.1040A>T p.Y347F | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.279); called by muse, mutect2
- GZMA | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- H1-8 | c.15C>A p.S5R | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- KIAA0586 | c.1141A>G p.S381G (on ENST00000619416 / NM_001244190.2; = p.S396G on NM_014749.5) | Missense Mutation (SNP) | VAF 47/208 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- KLHL6 | c.1757T>A p.L586Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KRTAP10-3 | c.374G>C p.C125S | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.321); called by muse, mutect2
- KRTAP4-16 | c.419A>G p.H140R | Missense Mutation (SNP) | VAF 47/287 reads (16%) | SIFT tolerated (0.11); called by muse, mutect2, varscan2
- LILRA6 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 75/230 reads (33%) | called by muse, mutect2, varscan2
- LONRF2 | c.719T>C p.L240S | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- LRP1B | c.11039T>A p.L3680H | Missense Mutation (SNP) | VAF 52/285 reads (18%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- LRRC4C | c.352G>C p.G118R | Missense Mutation (SNP) | VAF 61/252 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC6 | c.26T>G p.I9S | Missense Mutation (SNP) | VAF 156/388 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- LRRC7 | c.1227A>T p.R409S (on ENST00000651989 / NM_001370785.2; = p.R376S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 92/353 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- MACF1 | c.18980C>T p.T6327I (on ENST00000372915; = p.T4372I on NM_012090.5) | Missense Mutation (SNP) | VAF 32/164 reads (20%) | called by muse, mutect2, varscan2
- MAGEE2 | c.713A>T p.Y238F | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- MARVELD2 | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MCEMP1 | c.473A>G p.E158G | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MDM4 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 61/347 reads (18%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MED1 | c.700G>C p.D234H | Missense Mutation (SNP) | VAF 49/243 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- MICAL3 | c.1765G>T p.E589* | Nonsense Mutation (SNP) | VAF 33/131 reads (25%) | called by muse, mutect2, varscan2
- MTHFD1L | c.1589G>C p.R530T | Missense Mutation (SNP) | VAF 17/366 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYO16 | c.1074G>T p.L358F | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, varscan2
- MYO16 | c.3124A>T p.I1042F | Missense Mutation (SNP) | VAF 20/247 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- MYO18A | c.1958G>A p.G653D | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- NCAM2 | c.1387G>C p.A463P | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2
- NR0B1 | c.1046C>A p.A349D | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- NSD1 | c.1076G>A p.R359K | Missense Mutation (SNP) | VAF 30/301 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); called by muse, mutect2
- ONECUT2 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- ONECUT3 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- OR2T2 | c.973T>C p.*325Qext*? | Nonstop Mutation (SNP) | VAF 52/395 reads (13%) | called by muse, varscan2
- OR2T4 | c.881C>A p.P294H | Missense Mutation (SNP) | VAF 66/504 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR4K17 | c.720G>C p.L240F | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OR6B2 | c.541A>T p.I181F | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- OR6C70 | c.777G>T p.K259N | Missense Mutation (SNP) | VAF 53/244 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8U1 | c.206T>A p.V69E | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PCDHB11 | c.1347dup p.T450Hfs*226 | Frame Shift Ins (INS) | VAF 56/357 reads (16%) | called by pindel, varscan2
- PCDHB15 | c.1093G>T p.V365L | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PCDHGA7 | c.1233C>G p.D411E | Missense Mutation (SNP) | VAF 23/240 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHKB | c.1176G>C p.L392F | Missense Mutation (SNP) | VAF 52/444 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- PIK3CG | c.2322del p.Q775Rfs*17 | Frame Shift Del (DEL) | VAF 37/245 reads (15%) | called by mutect2, pindel, varscan2
- PNLIPRP1 | c.477C>A p.S159R | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POLR3G | c.80T>A p.L27* | Nonsense Mutation (SNP) | VAF 56/291 reads (19%) | called by muse, mutect2, varscan2
- POU3F2 | c.731C>G p.P244R | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PTEN | c.962_985del p.T321_A328del | In Frame Del (DEL) | VAF 56/278 reads (20%) | called by mutect2, pindel, varscan2
- PTH2R | c.1077-1G>T p.X359_splice | Splice Site (SNP) | VAF 30/141 reads (21%) | called by muse, varscan2
- PTPN13 | c.3854C>T p.S1285F (on ENST00000411767 / NM_080683.3; = p.S1266F on NM_006264.3) | Missense Mutation (SNP) | VAF 14/420 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, mutect2
- REST | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- RNF113B | c.394C>G p.Q132E | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- RNF14 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RNPEP | c.1762T>G p.F588V | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- RYR3 | c.12815G>C p.G4272A (on ENST00000389232; = p.G4273A on NM_001036.6) | Missense Mutation (SNP) | VAF 56/328 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SCN4A | c.3903del p.K1302Rfs*4 | Frame Shift Del (DEL) | VAF 21/118 reads (18%) | called by mutect2, pindel, varscan2
- SCN7A | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SEMA5A | c.1362G>T p.R454S | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC34A3 | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SLC6A3 | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- SUFU | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TAF15 | c.559C>T p.R187C (on ENST00000605844 / NM_139215.3; = p.R184C on NM_003487.4) | Missense Mutation (SNP) | VAF 56/302 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- TDRD15 | c.4690G>T p.E1564* | Nonsense Mutation (SNP) | VAF 16/148 reads (11%) | called by muse, mutect2, varscan2
- TECTB | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 63/318 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM4 | c.7145A>T p.Y2382F | Missense Mutation (SNP) | VAF 36/463 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2
- TLN2 | c.1803G>T p.M601I | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.309); called by muse, mutect2
- TMEM200A | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TNN | c.2641G>T p.A881S | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- TNNI3K | c.2278G>T p.V760L | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRDN | c.1632C>G p.D544E | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2
- TRIM51 | c.551A>G p.Q184R | Missense Mutation (SNP) | VAF 73/404 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UGT2A3 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 10/229 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- UMOD | c.1738C>A p.P580T | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP39 | c.394A>G p.N132D | Missense Mutation (SNP) | VAF 31/294 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- UTP20 | c.7657-4_7660delinsTTTTTTTT p.X2553_splice | Splice Site (ONP) | VAF 6/49 reads (12%) | called by pindel, varscan2*
- WASHC2C | c.2014G>T p.D672Y | Missense Mutation (SNP) | VAF 48/440 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZC3H11A | c.1567C>T p.L523F | Missense Mutation (SNP) | VAF 57/325 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZFHX3 | c.3753G>T p.M1251I | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ZNF175 | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 29/277 reads (10%) | called by muse, mutect2, varscan2
- ZNF215 | c.181G>T p.G61W | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ZNF248 | c.784A>T p.R262* | Nonsense Mutation (SNP) | VAF 40/164 reads (24%) | called by muse, mutect2, varscan2
- ZNF37A | c.4A>G p.I2V | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- ZNF385D | c.422C>A p.T141N | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, varscan2
- ZNF469 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- ZNF506 | c.770A>G p.Y257C | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- ZNF679 | c.401G>T p.C134F | Missense Mutation (SNP) | VAF 74/511 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ABCG4 | c.598C>T p.L200= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, varscan2
- ADGRB3 | c.2700A>G p.A900= | Silent (SNP) | VAF 38/306 reads (12%) | called by muse, mutect2, varscan2
- ADGRG4 | c.6150G>A p.A2050= | Silent (SNP) | VAF 88/240 reads (37%) | catalogued as rs770791343; called by muse, mutect2, varscan2
- AHNAK2 | c.10179G>A p.K3393= | Silent (SNP) | VAF 50/197 reads (25%) | catalogued as rs1458188854, COSV60910120; called by muse, mutect2, varscan2
- ANKRD2 | c.669C>T p.R223= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs559852218; called by muse, mutect2, varscan2
- AOPEP | c.2367C>T p.A789= (on ENST00000375315 / NM_001193329.1; = p.A690= on NM_032823.5) | Silent (SNP) | VAF 17/147 reads (12%) | called by muse, mutect2, varscan2
- APC | c.6366A>T p.A2122= | Silent (SNP) | VAF 34/359 reads (9%) | catalogued as rs370948574; ClinVar: likely benign; called by muse, mutect2
- ATRX | c.5511G>C p.V1837= | Silent (SNP) | VAF 96/261 reads (37%) | called by muse, mutect2, varscan2
- BBS10 | c.1788T>C p.A596= | Silent (SNP) | VAF 12/114 reads (11%) | called by muse, mutect2, varscan2
- BCAS1 | c.564C>A p.P188= | Silent (SNP) | VAF 51/282 reads (18%) | catalogued as COSV65086026; called by muse, mutect2, varscan2
- BNIPL | c.708A>G p.E236= | Silent (SNP) | VAF 33/240 reads (14%) | called by muse, mutect2, varscan2
- C16orf89 | c.444C>T p.F148= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs367564976; called by muse, mutect2, varscan2
- CDH15 | c.1299C>A p.T433= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as rs1244904767; called by muse, mutect2, varscan2
- CELSR1 | c.5238C>T p.N1746= | Silent (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- COL6A3 | c.6201G>A p.E2067= | Silent (SNP) | VAF 74/448 reads (17%) | called by muse, mutect2, varscan2
- CYLC2 | c.888C>A p.A296= | Silent (SNP) | VAF 42/319 reads (13%) | catalogued as COSV66339858; called by muse, mutect2, varscan2
- DAO | c.798G>T p.L266= | Silent (SNP) | VAF 64/355 reads (18%) | called by muse, mutect2, varscan2
- DCLK2 | c.474C>A p.T158= | Silent (SNP) | VAF 45/174 reads (26%) | called by muse, mutect2, varscan2
- DDI1 | c.693A>T p.I231= | Silent (SNP) | VAF 64/282 reads (23%) | called by muse, mutect2, varscan2
- DPRX | c.303G>A p.L101= | Silent (SNP) | VAF 12/182 reads (7%) | catalogued as COSV64949585, COSV64949874; called by muse, mutect2
- ENTPD2 | c.825G>T p.L275= | Silent (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- GRAMD4 | c.1662G>A p.R554= | Silent (SNP) | VAF 30/221 reads (14%) | called by muse, mutect2, varscan2
- GRB10 | c.891G>A p.L297= (on ENST00000398812; = p.L239= on NM_001001550.3) | Silent (SNP) | VAF 77/446 reads (17%) | catalogued as rs1028578853; called by muse, mutect2, varscan2
- HGF | c.225T>A p.T75= | Silent (SNP) | VAF 94/569 reads (17%) | called by muse, mutect2, varscan2
- HK2 | c.285G>T p.V95= | Silent (SNP) | VAF 81/382 reads (21%) | called by muse, mutect2, varscan2
- IGKV1D-43 | c.348C>G p.T116= | Silent (SNP) | VAF 17/199 reads (9%) | called by muse, mutect2
- ITPR2 | c.4128C>T p.I1376= | Silent (SNP) | VAF 82/204 reads (40%) | called by muse, mutect2, varscan2
- IZUMO3 | c.78C>A p.P26= | Silent (SNP) | VAF 479/823 reads (58%) | called by muse, mutect2, varscan2
- KIAA1549L | c.4140C>T p.S1380= (on ENST00000321505; = p.S1677= on NM_012194.3) | Silent (SNP) | VAF 23/74 reads (31%) | called by muse, mutect2, varscan2
- KIF21B | c.865C>A p.R289= | Silent (SNP) | VAF 21/155 reads (14%) | called by muse, mutect2, varscan2
- LRFN2 | c.972C>A p.A324= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100599882; called by muse, mutect2, varscan2
- MAGEC1 | c.402C>A p.S134= | Silent (SNP) | VAF 33/88 reads (38%) | called by muse, mutect2, varscan2
- MAGI2 | c.1041A>G p.E347= | Silent (SNP) | VAF 10/235 reads (4%) | called by muse, mutect2
- MEF2C | c.783A>T p.P261= | Silent (SNP) | VAF 46/502 reads (9%) | called by muse, mutect2
- NALCN | c.454C>A p.R152= | Silent (SNP) | VAF 23/330 reads (7%) | catalogued as COSV51935567; called by muse, mutect2
- NHLRC3 | c.252C>T p.I84= | Silent (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- NLRP8 | c.996C>A p.I332= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV52592802; called by muse, mutect2, varscan2
- NLRP9 | c.45G>A p.L15= | Silent (SNP) | VAF 40/144 reads (28%) | catalogued as COSV60462310, COSV60466030; called by muse, varscan2
- NOTUM | c.510C>T p.P170= | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as rs1252345846; called by muse, mutect2, varscan2
- OR10H5 | c.483G>T p.S161= | Silent (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- OR2M7 | c.792T>C p.S264= | Silent (SNP) | VAF 20/151 reads (13%) | called by muse, mutect2, varscan2
- OR4A15 | c.885C>T p.A295= | Silent (SNP) | VAF 15/148 reads (10%) | catalogued as rs776736667, COSV59034307; called by muse, mutect2, varscan2
- OR9Q2 | c.480G>A p.T160= | Silent (SNP) | VAF 57/343 reads (17%) | catalogued as rs773474840, COSV61111345; called by muse, mutect2, varscan2
- PAPPA2 | c.1434T>A p.L478= | Silent (SNP) | VAF 81/376 reads (22%) | called by muse, mutect2, varscan2
- PCDHGA2 | c.1935C>A p.A645= | Silent (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- PCDHGA9 | c.651C>T p.G217= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV54025193; called by muse, mutect2, varscan2
- PDE3B | c.2265G>T p.R755= | Silent (SNP) | VAF 26/158 reads (16%) | called by muse, mutect2, varscan2
- PHLDB2 | c.2073C>T p.T691= | Silent (SNP) | VAF 70/334 reads (21%) | catalogued as rs1455068262; called by muse, mutect2, varscan2
- PON3 | c.600C>T p.R200= | Silent (SNP) | VAF 129/623 reads (21%) | catalogued as rs768885543; called by muse, mutect2, varscan2
- PRAMEF12 | c.735C>T p.C245= | Silent (SNP) | VAF 59/273 reads (22%) | called by muse, mutect2, varscan2
- PRKDC | c.7014G>A p.E2338= | Silent (SNP) | VAF 50/146 reads (34%) | called by muse, mutect2, varscan2
- PRSS35 | c.951T>A p.A317= | Silent (SNP) | VAF 80/336 reads (24%) | called by muse, mutect2, varscan2
- PTPRN2 | c.3012G>A p.E1004= | Silent (SNP) | VAF 16/106 reads (15%) | called by muse, varscan2
- PTPRO | c.2550G>A p.Q850= | Silent (SNP) | VAF 78/546 reads (14%) | called by muse, mutect2, varscan2
- RBM33 | c.1611G>C p.P537= | Silent (SNP) | VAF 48/260 reads (18%) | catalogued as COSV56633531, COSV56633689; called by muse, mutect2, varscan2
- SAMD4A | c.1380G>T p.T460= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- SH3PXD2B | c.1287G>A p.K429= (on ENST00000636523; = p.K415= on NM_001308175.1) | Silent (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- TBC1D2 | c.1209C>T p.H403= | Silent (SNP) | VAF 11/113 reads (10%) | catalogued as rs528252959; called by muse, mutect2
- TM4SF18 | c.519G>A p.V173= | Silent (SNP) | VAF 24/475 reads (5%) | called by muse, mutect2
- TMEM123 | c.564A>G p.K188= | Silent (SNP) | VAF 19/168 reads (11%) | called by muse, mutect2, varscan2
- TTC7A | c.849G>T p.A283= | Silent (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- USP45 | c.141G>A p.V47= | Silent (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- WSCD1 | c.396C>T p.P132= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs775999396; called by muse, mutect2, varscan2
- ZNF773 | c.549C>A p.A183= | Silent (SNP) | VAF 74/343 reads (22%) | called by muse, mutect2, varscan2
- AC012485.1 | n.310C>T | RNA (SNP) | VAF 34/407 reads (8%) | catalogued as rs944132175; called by muse, mutect2
- AL355390.1 | n.420C>A | RNA (SNP) | VAF 46/160 reads (29%) | called by muse, mutect2, varscan2
- ANO3 | c.-8G>C | 5'UTR (SNP) | VAF 33/190 reads (17%) | catalogued as COSV99885018; called by muse, mutect2, varscan2
- ARHGAP24 | c.391+7152G>T | Intron (SNP) | VAF 34/149 reads (23%) | called by muse, mutect2, varscan2
- BRD2 | c.-932T>C | 5'UTR (SNP) | VAF 37/168 reads (22%) | called by muse, mutect2, varscan2
- DCHS2 | n.4879C>G | RNA (SNP) | VAF 41/198 reads (21%) | called by muse, mutect2, varscan2
- DPPA4 | c.679+23A>T | Intron (SNP) | VAF 36/320 reads (11%) | called by muse, mutect2, varscan2
- F11 | c.*9C>T | 3'UTR (SNP) | VAF 46/225 reads (20%) | called by muse, mutect2, varscan2
- FAM183BP | n.833C>T | RNA (SNP) | VAF 28/112 reads (25%) | called by muse, mutect2, varscan2
- FOLH1B | n.1565G>T | RNA (SNP) | VAF 22/320 reads (7%) | called by muse, mutect2
- GIPR | c.924+43C>G | Intron (SNP) | VAF 30/220 reads (14%) | called by muse, mutect2, varscan2
- GLB1L3 | c.1099+67G>T | Intron (SNP) | VAF 10/34 reads (29%) | called by muse, varscan2
- HCRTR2 | c.*5T>A | 3'UTR (SNP) | VAF 68/322 reads (21%) | called by muse, mutect2, varscan2
- HLA-G | chr6:29826997 G>C | 5'Flank (SNP) | VAF 58/221 reads (26%) | catalogued as COSV100826952; called by muse, mutect2, varscan2
- INSL3 | c.190+861C>G | Intron (SNP) | VAF 21/98 reads (21%) | called by muse, mutect2, varscan2
- MKRN1 | c.186-3305A>G | Intron (SNP) | VAF 4/45 reads (9%) | catalogued as rs1256297728; called by muse, mutect2
- MOG | c.593-113C>T | Intron (SNP) | VAF 81/371 reads (22%) | called by muse, mutect2, varscan2
- MTERF4 | c.-14A>G | 5'UTR (SNP) | VAF 6/42 reads (14%) | catalogued as rs766935642; called by mutect2, varscan2
- OR9Q1 | c.-15+53545del | Intron (DEL) | VAF 52/281 reads (19%) | called by mutect2, pindel, varscan2
- PCDHB12 | c.*108C>G | 3'UTR (SNP) | VAF 37/126 reads (29%) | catalogued as rs782537439; called by muse, mutect2, varscan2
- PDXK | c.142+2851G>A | Intron (SNP) | VAF 14/226 reads (6%) | catalogued as rs1204051447; called by muse, mutect2
- REG1B | c.183+21G>A | Intron (SNP) | VAF 56/234 reads (24%) | called by muse, varscan2
- RNF217-AS1 | n.1056G>A | RNA (SNP) | VAF 57/259 reads (22%) | called by muse, mutect2, varscan2
- SERF2 | c.*104G>A | 3'UTR (SNP) | VAF 12/113 reads (11%) | catalogued as rs757746110; called by muse, mutect2, varscan2
- SKP1P2 | n.97G>T | RNA (SNP) | VAF 138/379 reads (36%) | called by muse, mutect2, varscan2
- SLC10A2 | c.*40C>A | 3'UTR (SNP) | VAF 22/191 reads (12%) | catalogued as COSV99808236; called by muse, mutect2, varscan2
- SLC6A3 | c.928-27G>A | Intron (SNP) | VAF 29/141 reads (21%) | catalogued as rs1448650933; called by muse, mutect2, varscan2
- SNX22 | c.460+55C>G | Intron (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
- ST7 | c.151+12405del | Intron (DEL) | VAF 25/144 reads (17%) | called by mutect2, pindel, varscan2
- STXBP2 | c.247-191G>A | Intron (SNP) | VAF 29/178 reads (16%) | called by muse, mutect2, varscan2
- TCF3 | c.1586+41C>T | Intron (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99513390; called by muse, mutect2, varscan2
- VAPB | c.*4573C>G | 3'UTR (SNP) | VAF 62/514 reads (12%) | called by muse, mutect2, varscan2
- VSTM2A | c.*61C>A | 3'UTR (SNP) | VAF 80/434 reads (18%) | called by mutect2, varscan2
- ZNF467 | chr7:149776982 G>T | 5'Flank (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- ZNF525 | c.142+459G>C | Intron (SNP) | VAF 11/105 reads (10%) | called by muse, mutect2
